Surgical pathology report (de-identified scan), TCGA case TCGA-XE-A8H0, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-A8H0-01A (Primary Tumor).

[page 1 of 2]
S U R G I C A L P A T H O L O G Y R E P O R T

Collected Date and Time

Received Date and Time

Accession Number

Post-Op Dx: Same

GROSS EXAMINATION:

The specimen is received in formalin and labeled "Left testicle".. It consists of a radical orchiectomy specimen which measures overall 18 x 6 x 3 cm. The testis itself measures 7 x 6 x 3 cm. The spermatic cord measures 11 cm in length by 2 cm in diameter. The outer tunica vaginalis which is freely movable is inked black and the specimen is serially sectioned. Sectioning reveals multinodular, cream to tan fleshy mass lesion measuring 5.0 x 2.0 x 3.0 cm. Areas of focal necrosis and hemorrhage are appreciated. Representative sections are submitted in 10 cassettes.

SECTIONS:

- A1: cord margin
- A2: mid portion of the cord
- A3-8: tumor
- A9: tumor with normal testicle
- A10: epididymis

ICD-O-3

Seminoma 9061/3

MICROSCOPIC EXAMINATION:

See final microscopic-diagnosis.

Sate ^{666*} Testis NOS C62.9
part
① Testicle NOS C62.9
JW 11/24/13

Ordering:
Admitting:
Consulting:

Chart
Printed:

PRINTED BY:

DATE

[page 2 of 2]
S U R G I C A L P A T H O L O G Y R E P O R T

Collected Date and Time

Received Date and Time

Accession Number

DIAGNOSIS:

LEFT RADICAL ORCHIECTOMY, PLACEMENT OF LEFT TESTICULAR PROSTHESIS:

LEFT TESTICLE:

- MALIGNANT GERM CELL TUMOR (SEMINOMA)
- TUMOR IS CONFINED TO TESTIS
- EXTENDING INTO BUT NOT THROUGH TUNICA ALBUGINEA
- EPIDIDYMIS, FREE OF MALIGNANCY
- SPERMATIC CORD INCLUDING RESECTION MARGINS, FREE OF MALIGNANCY
- LYMPHOVASCULAR INVASION IDENTIFIED

PATHOLOGIC TNM STAGE: pT2NXMX

Electronically signed by

COMMENT:

Immunohistochemical studies on blocks A7 and A8, showing different tumor features, reveal positive for PLAP, negative for cytokeratin, AFP, and CD30 in both sections, consistent with seminoma.

SPECIMEN SOURCE:

"Left testicle"

CLINICAL INFORMATION:

Pre-Op Dx: Left scrotal mass

Ordering:

Admitting:

Consulting:

Chart Request ID:

Printed:

DATE

Criteria	10/23/13	Yes	No
IHPAA Discrepancy			✓
Metastatic/Synchronous Primary Noted			✓

Source: NCI Genomic Data Commons file 34ca9f0c-a5f9-4888-a86b-4ee4d7154964 (TCGA-XE-A8H0-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).